FM case AD5205 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/af39838f-6e1f-4954-9daf-561843564d7a

Male, 72.7 years: Acinar cell tumor (ICD-O-3 8550/1) of the major salivary gland; specimen biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
